Somatic mutation profile of tumor specimen ALCH-B24R-TTP1-A (aliquot ALCH-B24R-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B24R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.9 years (25,179 days).
Specimen ALCH-B24R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0134b2ef-aea9-4c01-a4ef-e12d64e55da9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B24R-NB1-A (Blood Derived Normal), aliquot ALCH-B24R-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72866235-3bfb-4d66-9a3a-5af475b9636e

The open-access MAF lists 519 somatic variants for this specimen: 357 protein-altering or splice-affecting, 98 silent, 64 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 98, Nonsense Mutation 30, Intron 27, Splice Site 12, RNA 11, 3'UTR 10, 5'UTR 8, 5'Flank 7, Frame Shift Del 6, Splice Region 6, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.3856G>T p.E1286* | Nonsense Mutation (SNP) | VAF 51/456 reads (11%) | catalogued as rs1569562570, COSV63789319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.157T>C p.F53L | Missense Mutation (SNP) | VAF 67/600 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as rs1057519728, COSV61068605, COSV61070825, COSV61071840; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 29/249 reads (12%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1797G>C p.M599I (on ENST00000404938 / NM_001163941.2; = p.M154I on NM_178559.6) | Missense Mutation (SNP) | VAF 25/341 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1324236207; called by muse, mutect2
- ADA | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 73/823 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV63068987; called by muse, mutect2
- ADAMTS1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 29/537 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.368); catalogued as rs931544150; called by muse, mutect2
- ADGRB3 | c.3091G>C p.A1031P | Missense Mutation (SNP) | VAF 45/462 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV53235954, COSV53255477; called by muse, mutect2, varscan2
- ADGRB3 | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs761863915, COSV99486169; called by muse, varscan2
- AFG3L2 | c.127G>T p.V43F | Missense Mutation (SNP) | VAF 26/403 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV52313720; called by muse, mutect2
- AKR1C1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as rs1460086454; called by muse, mutect2
- AMER1 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 31/440 reads (7%) | catalogued as COSV57667613, COSV57671021; called by muse, mutect2
- APBA2 | c.1814C>A p.P605Q | Missense Mutation (SNP) | VAF 52/566 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67105398; called by muse, mutect2
- AR | c.1823G>T p.R608L | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM920073, COSV65954700; called by muse, mutect2
- ATG2A | c.2292G>C p.E764D | Missense Mutation (SNP) | VAF 28/442 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV65965623; called by muse, mutect2
- BCL2L12 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 11/319 reads (3%) | catalogued as rs1490708452, COSV55862547; called by muse, mutect2
- CACNA1S | c.4243G>A p.G1415R | Missense Mutation (SNP) | VAF 32/391 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886045796; ClinVar: uncertain significance; called by muse, mutect2
- CCT8L2 | c.1201C>A p.Q401K | Missense Mutation (SNP) | VAF 64/500 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV63462865; called by muse, mutect2, varscan2
- CD207 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs782521829, COSV69652041; called by muse, mutect2
- CD300LB | c.88G>T p.G30W | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761612833; called by muse, mutect2
- CD96 | c.799G>C p.A267P (on ENST00000283285 / NM_198196.3; = p.A251P on NM_005816.5) | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51921112; called by muse, mutect2, varscan2
- CDC42BPG | c.2224A>T p.R742W | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV61346106; called by muse, mutect2
- CELSR2 | c.3047G>T p.R1016L | Missense Mutation (SNP) | VAF 34/537 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54781056; called by muse, mutect2
- CENPJ | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV67883116, COSV67883522; called by muse, mutect2, varscan2
- CFAP47 | c.1940G>T p.S647I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.254); catalogued as COSV52880233; called by muse, mutect2, varscan2
- CHRD | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52609244; called by muse, mutect2, varscan2
- CHST2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 62/628 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58885111; called by muse, mutect2
- CLCN1 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 48/714 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100578411; called by muse, mutect2
- COL11A1 | c.2222C>A p.S741Y | Missense Mutation (SNP) | VAF 54/721 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1205519938; called by muse, mutect2
- COL5A2 | c.3310-1G>T p.X1104_splice | Splice Site (SNP) | VAF 26/374 reads (7%) | catalogued as COSV100880001; called by muse, mutect2
- COL9A2 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 38/598 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444032636; called by muse, mutect2
- CREB5 | c.182C>T p.T61I (on ENST00000357727 / NM_182898.4; = p.T54I on NM_004904.3) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63217545; called by muse, mutect2, varscan2
- CTNNA3 | c.1610C>A p.A537E | Missense Mutation (SNP) | VAF 63/884 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65597724; called by muse, mutect2
- DCAF8L1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 17/228 reads (7%) | catalogued as COSV101491429; called by muse, mutect2
- EFCAB2 | c.204_205insCCTTC p.R69Pfs*22 | Frame Shift Ins (INS) | VAF 12/172 reads (7%) | catalogued as rs1356674089; called by mutect2, pindel
- ELAVL2 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV56358243; called by muse, mutect2, varscan2
- EPHB6 | c.634G>T p.V212L | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.185); catalogued as rs1469509217; called by muse, mutect2, varscan2
- EXOC2 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV57869717; called by muse, mutect2
- FAM47A | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100650125, COSV60496194; called by muse, varscan2
- FCRL1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1032164101, COSV100839923, COSV63825161; called by muse, mutect2
- FERD3L | c.320del p.N107Tfs*47 | Frame Shift Del (DEL) | VAF 55/461 reads (12%) | catalogued as COSV99284953; called by mutect2, pindel, varscan2
- FLG2 | c.1721C>A p.S574* | Nonsense Mutation (SNP) | VAF 79/605 reads (13%) | catalogued as COSV101165581; called by muse, mutect2, varscan2
- FSTL5 | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV60186524, COSV60208227; called by muse, mutect2, varscan2
- GAN | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101634039; called by muse, mutect2, varscan2
- GCK | c.1020-7C>A | Splice Region (SNP) | VAF 46/342 reads (13%) | catalogued as rs779087432; called by muse, mutect2, varscan2
- GCNT4 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 16/539 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as COSV59281273; called by muse, mutect2
- GJC2 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812998; called by muse, mutect2
- GRM1 | c.1305C>A p.H435Q | Missense Mutation (SNP) | VAF 109/708 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.191); catalogued as COSV51207893; called by muse, mutect2, varscan2
- HCN1 | c.2112C>G p.C704W | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.932); catalogued as COSV57522971; called by muse, mutect2, varscan2
- HEPACAM2 | c.887G>T p.G296V (on ENST00000394468 / NM_001039372.4; = p.G284V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59063783; called by muse, mutect2
- HNRNPUL1 | c.2539G>A p.G847R | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1454168002; called by muse, mutect2
- HOXB9 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 54/580 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60817882; called by muse, mutect2
- HTR3B | c.1105G>T p.G369* | Nonsense Mutation (SNP) | VAF 17/197 reads (9%) | catalogued as COSV99492322; called by muse, mutect2
- HTR5A | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs199909178; called by muse, mutect2
- IFFO2 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 29/402 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV69085562; called by muse, mutect2
- IFI16 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 88/620 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV99856864; called by muse, mutect2, varscan2
- IL11RA | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 26/373 reads (7%) | catalogued as rs768658734; called by muse, mutect2
- IL21R | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV61968685; called by muse, mutect2
- IRS4 | c.1772del p.G591Afs*20 | Frame Shift Del (DEL) | VAF 56/470 reads (12%) | catalogued as rs780982673; called by mutect2, varscan2
- KIF1B | c.1327C>G p.P443A (on ENST00000377086 / NM_001365952.1; = p.P397A on NM_015074.3) | Missense Mutation (SNP) | VAF 37/546 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV55807714; called by muse, mutect2
- KLF4 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.091); catalogued as COSV65928968; called by muse, mutect2
- KLHL11 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555623398; called by muse, mutect2, varscan2
- KRT32 | c.1247C>A p.S416Y | Missense Mutation (SNP) | VAF 52/608 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV56788147; called by muse, mutect2
- LILRA4 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1171777029; called by muse, mutect2, varscan2
- LILRB1 | c.1635C>A p.T545= (on ENST00000427581; = p.T495= on NM_006669.6) | Splice Region (SNP) | VAF 13/132 reads (10%) | catalogued as COSV100208048; called by muse, mutect2, varscan2
- LRRC14B | c.460C>A p.R154S | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs376391252; called by muse, mutect2, varscan2
- LRTM2 | c.881C>A p.P294Q | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.063); catalogued as COSV99765455; called by muse, mutect2
- MARK2 | c.1378G>T p.G460C (on ENST00000402010 / NM_001039469.2; = p.G459C on NM_004954.5) | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs140950433; called by muse, mutect2
- MROH2A | c.1325C>A p.S442Y | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.391); catalogued as rs576634340; called by muse, mutect2, varscan2
- MYBPC3 | c.1672G>T p.A558S | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as COSV99920033; called by muse, mutect2, varscan2
- MYH2 | c.2668A>T p.K890* | Nonsense Mutation (SNP) | VAF 60/564 reads (11%) | catalogued as COSV99819920; called by muse, varscan2
- NKX2-1 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 66/820 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs575848748; called by muse, mutect2
- NRP2 | c.2236A>C p.I746L | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55929934; called by muse, mutect2, varscan2
- NTN4 | c.1273G>T p.G425W | Missense Mutation (SNP) | VAF 51/476 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59223058; called by muse, mutect2, varscan2
- OR10J5 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs772511572; called by muse, mutect2, varscan2
- OR10K2 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 66/566 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59222536; called by muse, varscan2
- OR4C11 | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56352721; called by muse, mutect2
- OR4Q2 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV101607675; called by muse, mutect2, varscan2
- OR51V1 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs142750105; called by muse, varscan2
- OR52J3 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 62/558 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs773085013, COSV66747281; called by muse, mutect2, varscan2
- OSBPL11 | c.93C>A p.N31K | Missense Mutation (SNP) | VAF 40/500 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs146199292; called by muse, mutect2
- OTOF | c.5514C>A p.F1838L (on ENST00000272371 / NM_194248.3; = p.F1071L on NM_004802.4) | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.211); catalogued as rs1309761924; called by muse, mutect2
- PASD1 | c.1724A>G p.N575S | Missense Mutation (SNP) | VAF 40/680 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1258783169; called by muse, mutect2
- PAX2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 52/682 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.423); catalogued as COSV62291139, COSV62291448; called by muse, mutect2
- PCDHA11 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 24/664 reads (4%) | catalogued as COSV56502825; called by muse, mutect2
- PCDHB8 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 52/1994 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as rs1372149225, COSV50760033; called by muse, mutect2
- PELI1 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1325330746; called by muse, varscan2
- PLPPR5 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | catalogued as COSV54174952, COSV99586878; called by muse, mutect2
- PNLIPRP2 | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100077727; called by muse, mutect2
- POPDC2 | c.492-1G>T p.X164_splice | Splice Site (SNP) | VAF 25/231 reads (11%) | catalogued as COSV51742765; called by muse, mutect2, varscan2
- PRG4 | c.341C>A p.P114Q | Missense Mutation (SNP) | VAF 95/795 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148063116; called by muse, mutect2, varscan2
- PRMT5 | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as COSV53547316; called by muse, mutect2
- RCHY1 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1403059058; called by muse, mutect2
- RIMS2 | c.1907G>T p.R636I (on ENST00000666250 / NM_001348490.2; = p.R444I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99212762; called by muse, mutect2, varscan2
- RNASE11 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 20/349 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.657); catalogued as COSV100250512; called by muse, mutect2
- ROBO4 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 40/343 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV60621322; called by muse, mutect2, varscan2
- RTL4 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61206569, COSV61207484; called by muse, mutect2, varscan2
- SCN4A | c.5284G>A p.G1762R | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs763493738, COSV101438272; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / benign / likely benign; called by muse, mutect2, varscan2
- SETBP1 | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 24/706 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs945468556, COSV56318637; called by muse, mutect2
- SHROOM2 | c.2860G>T p.V954F | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.168); catalogued as rs1469108719; called by muse, mutect2, varscan2
- SHROOM2 | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs775435312, COSV66604634; called by muse, mutect2
- SI | c.3961G>T p.V1321F | Missense Mutation (SNP) | VAF 45/554 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV52285162; called by muse, mutect2
- SIGLEC12 | c.771G>T p.W257C (on ENST00000291707 / NM_053003.4; = p.W139C on NM_033329.2) | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1204890251, COSV99389463; called by muse, mutect2
- SLA | c.794G>A p.S265N (on ENST00000338087 / NM_001045556.3; = p.S305N on NM_006748.4) | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.212); catalogued as rs765314621; called by muse, mutect2, varscan2
- SLC10A2 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV55357114; called by muse, mutect2, varscan2
- SLC12A5 | c.2030G>T p.R677L (on ENST00000454036 / NM_001134771.2; = p.R654L on NM_020708.5) | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs760824180, COSV54790694; called by muse, mutect2
- SLC14A2 | c.1384C>A p.P462T | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV54912966; called by muse, mutect2
- SPTBN4 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 150/365 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.382); catalogued as rs1261686486; called by muse, mutect2, varscan2
- ST8SIA2 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 10/87 reads (11%) | PolyPhen probably damaging (1); catalogued as COSV51567470, COSV99184363; called by muse, mutect2
- STAG1 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 24/448 reads (5%) | catalogued as COSV52624323; called by muse, mutect2
- TAOK2 | c.3326G>T p.R1109L | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.288); catalogued as COSV54228830; called by muse, mutect2
- TFDP2 | c.793C>T p.P265S (on ENST00000489671 / NM_001178139.2; = p.P205S on NM_006286.5) | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs1295626867; called by muse, mutect2, varscan2
- TIMD4 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 58/608 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV50854082; called by muse, mutect2, varscan2
- TLL1 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 64/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50339050; called by muse, mutect2, varscan2
- TRPC7 | c.256G>T p.V86L | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61452394; called by muse, mutect2, varscan2
- TSHZ3 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1263564266; called by muse, mutect2, varscan2
- UGGT1 | c.3247G>C p.E1083Q | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.833); catalogued as COSV52134674; called by muse, mutect2, varscan2
- UNC5D | c.2687G>T p.S896I | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54772032; called by muse, mutect2
- USH2A | c.12119G>A p.R4040H | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1238450377; called by muse, mutect2, varscan2
- USP7 | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 39/587 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs1567217225; called by muse, mutect2
- VSTM2L | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs150114807; called by muse, mutect2
- ZBTB26 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 28/484 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.282); catalogued as COSV65402885; called by muse, mutect2
- ZNF257 | c.426C>A p.S142R | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV71312465; called by muse, mutect2, varscan2
- ZNF382 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV53089963; called by muse, mutect2, varscan2
- ZNF521 | c.3751G>T p.G1251W | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64123912; called by muse, mutect2
- ZNF800 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99758235; called by muse, mutect2
- ZNF831 | c.3772C>A p.Q1258K | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.066); catalogued as rs766941481, COSV64038469; called by muse, mutect2
- ZSCAN26 | c.1289C>T p.A430V (on ENST00000623276 / NM_001111039.2; = p.A296V on NM_152736.5) | Missense Mutation (SNP) | VAF 53/498 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1242430140; called by muse, mutect2, varscan2
- ZWINT | c.256+1G>T p.X86_splice | Splice Site (SNP) | VAF 14/183 reads (8%) | catalogued as COSV59185875; called by muse, mutect2
- ABCB1 | c.2240C>A p.T747K | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AC011840.1 | n.996-3C>A | Splice Region (SNP) | VAF 16/372 reads (4%) | called by muse, mutect2
- ACP6 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ADAM19 | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 61/562 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS13 | c.3665G>T p.G1222V | Missense Mutation (SNP) | VAF 46/689 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ADGRG2 | c.963G>T p.Q321H (on ENST00000379869 / NM_001079858.3; = p.Q318H on NM_005756.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.438); called by muse, varscan2
- AFF2 | c.2039C>A p.P680H | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AGAP1 | c.1787G>A p.S596N (on ENST00000304032 / NM_001037131.3; = p.S543N on NM_014914.5) | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AGXT | c.890A>G p.Y297C | Missense Mutation (SNP) | VAF 28/294 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); called by muse, mutect2
- AHDC1 | c.3584A>T p.Q1195L | Missense Mutation (SNP) | VAF 25/442 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- AL592490.1 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AMOT | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 45/348 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AMY2B | c.1463G>T p.G488V | Missense Mutation (SNP) | VAF 36/1120 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANTXR1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 51/479 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APEH | c.879G>A p.E293= | Splice Region (SNP) | VAF 37/309 reads (12%) | called by muse, mutect2, varscan2
- APOBR | c.2049G>T p.E683D (on ENST00000431282; = p.E692D on NM_018690.4) | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- AR | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 25/217 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARL9 | c.574G>A p.A192T (on ENST00000640821 / NM_001363794.2; = p.A50T on NM_206919.2) | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.063); called by muse, mutect2
- ARPP21 | c.1769C>A p.P590H | Missense Mutation (SNP) | VAF 62/671 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2
- ASIC2 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- ATF7IP | c.3400C>T p.P1134S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.155); called by muse, varscan2
- BMP2K | c.2845A>T p.S949C | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C1QL3 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 48/402 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- CACNA1H | c.4549G>T p.V1517L | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CCDC136 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 22/399 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCSER1 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 49/446 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- CD96 | c.799+1G>T p.X267_splice (on ENST00000283285 / NM_198196.3; = p.X251_splice on NM_005816.5) | Splice Site (SNP) | VAF 24/192 reads (13%) | called by muse, mutect2, varscan2
- CDHR4 | c.1134C>A p.F378L | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- CEP170 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 36/586 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNBD2 | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- CNKSR3 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 31/385 reads (8%) | called by muse, mutect2
- COCH | c.622C>A p.P208T (on ENST00000216361 / NM_001347720.1; = p.P143T on NM_004086.3) | Missense Mutation (SNP) | VAF 59/633 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- COL5A2 | c.3310G>T p.G1104C | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL7A1 | c.3001G>T p.G1001W | Missense Mutation (SNP) | VAF 78/686 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- COLQ | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 71/644 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CPS1 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 51/510 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); called by muse, varscan2
- CPXM2 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- CRTAP | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- CSMD1 | c.2235C>A p.N745K (on ENST00000520002; = p.N744K on NM_033225.6) | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CYP51A1 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- DCAF12L2 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 55/438 reads (13%) | called by muse, mutect2, varscan2
- DLG2 | c.1085G>T p.R362M | Missense Mutation (SNP) | VAF 27/451 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); called by muse, mutect2
- DNMT3L | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 57/322 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DPYD | c.1435G>T p.G479C | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DSEL | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- DTX1 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 48/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC2H1 | c.4735A>T p.T1579S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2428G>C p.A810P | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- EGF | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 50/465 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELMO2 | c.2061G>A p.M687I | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ERBB4 | c.1739G>T p.C580F | Missense Mutation (SNP) | VAF 53/860 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- EVI5L | c.2013G>T p.R671S | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- EYA1 | c.1738C>A p.L580I | Missense Mutation (SNP) | VAF 100/1071 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- FAM204A | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.347); called by muse, mutect2
- FAM47C | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2
- FAT2 | c.9896C>A p.S3299Y | Missense Mutation (SNP) | VAF 78/650 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, varscan2
- FBN2 | c.5720T>A p.L1907* | Nonsense Mutation (SNP) | VAF 59/673 reads (9%) | called by muse, mutect2
- FBXO34 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLG2 | c.1405C>A p.H469N | Missense Mutation (SNP) | VAF 47/367 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FOLH1B | n.1415-1G>A | Splice Site (SNP) | VAF 22/235 reads (9%) | called by muse, mutect2, varscan2
- FSIP2 | c.15630dup p.D5211Rfs*12 | Frame Shift Ins (INS) | VAF 10/108 reads (9%) | called by mutect2, pindel
- FSIP2 | c.17342T>C p.I5781T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GABRA4 | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2
- GCC1 | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 56/586 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2
- GCM1 | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GLI2 | c.2233C>A p.P745T (on ENST00000361492 / NM_001374353.1; = p.P762T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.583); called by muse, mutect2
- GNAT3 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GNAT3 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.371); called by muse, mutect2
- GRIPAP1 | c.356A>G p.E119G | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2
- GRPR | c.602A>T p.H201L | Missense Mutation (SNP) | VAF 66/560 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HDAC9 | c.555G>C p.L185F | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- HDAC9 | c.1331G>T p.R444I | Missense Mutation (SNP) | VAF 78/957 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HDX | c.901G>T p.G301* | Nonsense Mutation (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- HERC2 | c.8848G>T p.G2950W | Missense Mutation (SNP) | VAF 44/470 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2
- HMGCS2 | c.583G>T p.G195* | Nonsense Mutation (SNP) | VAF 42/674 reads (6%) | called by muse, mutect2
- HOXA13 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 109/761 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD3B2 | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 66/592 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IFFO1 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 125/911 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFNK | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2
- IGKV5-2 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 56/480 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- IQGAP2 | c.2095-1G>T p.X699_splice | Splice Site (SNP) | VAF 36/359 reads (10%) | called by muse, varscan2
- ISX | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 35/718 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2
- KCNMA1 | c.1881G>T p.K627N | Missense Mutation (SNP) | VAF 68/888 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.113); called by muse, mutect2
- KCNU1 | c.1373T>G p.L458R | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1109 | c.10364G>T p.G3455V | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- KIF1A | c.209A>C p.Q70P | Missense Mutation (SNP) | VAF 54/606 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KIF3B | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- KIF4A | c.2935C>A p.Q979K | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- LAMA5 | c.7894G>T p.A2632S | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- LANCL3 | c.1005G>C p.K335N | Missense Mutation (SNP) | VAF 39/356 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGR5 | c.2359T>A p.F787I | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- LIN28B | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.031); called by muse, mutect2
- LPIN1 | c.2165G>C p.C722S | Missense Mutation (SNP) | VAF 58/513 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LRIT2 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.143); called by muse, mutect2
- LRRC18 | c.767T>A p.I256K | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- LRRC43 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 43/371 reads (12%) | called by muse, mutect2, varscan2
- LRRC7 | c.538C>A p.Q180K (on ENST00000651989 / NM_001370785.2; = p.Q147K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/506 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2
- LRRC9 | c.3974C>A p.T1325K | Missense Mutation (SNP) | VAF 16/301 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- MAP2K4 | c.1192G>T p.V398F | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, varscan2
- MAP3K4 | c.3631G>T p.D1211Y | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, varscan2
- MAP4K5 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MDH2 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MGAM | c.4006G>T p.E1336* | Nonsense Mutation (SNP) | VAF 38/360 reads (11%) | called by muse, mutect2, varscan2
- MGAM | c.5062-1G>T p.X1688_splice | Splice Site (SNP) | VAF 56/464 reads (12%) | called by muse, mutect2, varscan2
- MISP | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MMGT1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- MROH2B | c.216C>G p.I72M | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MUC12 | c.4009G>T p.A1337S (on ENST00000379442; = p.A1194S on NM_001164462.1) | Missense Mutation (SNP) | VAF 162/1117 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MUC12 | c.15071T>C p.F5024S (on ENST00000379442; = p.F4881S on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT tolerated (0.18); called by muse, mutect2
- MUC5B | c.12053C>A p.P4018H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.425); called by mutect2, varscan2
- MYF6 | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH2 | c.1955C>A p.T652K | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- MYO1D | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 28/339 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAP1L3 | c.287T>G p.F96C | Missense Mutation (SNP) | VAF 26/578 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2
- NBEAL2 | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2
- NEIL3 | c.1100G>T p.C367F | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2
- NEXMIF | c.3705G>T p.E1235D | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NKX2-3 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- NLRP2 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NODAL | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 63/822 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); called by muse, mutect2
- NOMO1 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- NOVA1 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NPAP1 | c.2054C>A p.A685D | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.094); called by muse, mutect2
- NTRK2 | c.1742C>A p.A581E (on ENST00000323115 / NM_001369534.1; = p.A597E on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2
- NWD2 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OBSCN | c.12999G>T p.Q4333H | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- OR10Z1 | c.609T>A p.S203R | Missense Mutation (SNP) | VAF 31/503 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- OR11H6 | c.138C>A p.F46L | Missense Mutation (SNP) | VAF 21/355 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR14I1 | c.724del p.Q242Sfs*17 | Frame Shift Del (DEL) | VAF 17/172 reads (10%) | called by mutect2, pindel
- OR2L2 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR2T27 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.158); called by muse, mutect2
- OVCH1 | c.1897C>A p.H633N | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- PCDHA4 | c.1088C>A p.A363D | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PCDHB14 | c.694G>T p.V232L | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- PCLO | c.5218G>T p.D1740Y | Missense Mutation (SNP) | VAF 61/501 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCNX1 | c.3151-1G>A p.X1051_splice | Splice Site (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- PDCD4 | c.638C>A p.A213D | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2
- PDLIM4 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 66/590 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PEX12 | c.393_394del p.K132Afs*4 | Frame Shift Del (DEL) | VAF 42/448 reads (9%) | called by pindel, varscan2
- PHIP | c.3857A>T p.E1286V | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); called by muse, mutect2
- PHLDA1 | c.1060C>G p.P354A | Missense Mutation (SNP) | VAF 22/577 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); called by muse, mutect2
- PLD5 | c.1526del p.N509Tfs*55 (on ENST00000442594; = p.N447Tfs*55 on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 102/892 reads (11%) | called by pindel, varscan2
- PNMA5 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POPDC2 | c.492G>T p.R164= | Splice Region (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- POSTN | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2
- POTEI | c.229A>T p.K77* | Nonsense Mutation (SNP) | VAF 81/1711 reads (5%) | called by muse, mutect2
- PPP4R3C | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 28/207 reads (14%) | called by muse, mutect2, varscan2
- PPP5C | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 189/556 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRAMEF10 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 53/470 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCB | c.1331+1G>T p.X444_splice | Splice Site (SNP) | VAF 24/285 reads (8%) | called by muse, mutect2
- PROCA1 | c.394G>C p.E132Q (on ENST00000439862 / NM_001366301.1; = p.E104Q on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2
- PRR35 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PRRC2C | c.1756G>T p.E586* (on ENST00000367742; = p.E584* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 30/352 reads (9%) | called by muse, mutect2
- PSD | c.1613G>T p.R538L | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2
- PSTPIP2 | c.892G>T p.G298* | Nonsense Mutation (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2
- RANBP3 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- REXO4 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 34/740 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2
- RGPD3 | c.4280G>A p.W1427* | Nonsense Mutation (SNP) | VAF 36/1756 reads (2%) | called by muse, mutect2
- RIMS2 | c.2536G>T p.E846* (on ENST00000666250 / NM_001348490.2; = p.E654* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- RIMS2 | c.4513C>A p.Q1505K (on ENST00000666250 / NM_001348490.2; = p.Q1076K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/415 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RINT1 | c.1456C>T p.L486F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RSBN1L | c.209A>T p.Q70L | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- RTEL1 | c.2722A>G p.S908G | Missense Mutation (SNP) | VAF 48/631 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- RTL1 | c.1983G>T p.E661D | Missense Mutation (SNP) | VAF 55/575 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- RTL4 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR2 | c.6273G>C p.Q2091H | Missense Mutation (SNP) | VAF 44/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.8698G>T p.G2900* | Nonsense Mutation (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- RYR3 | c.4680C>A p.H1560Q | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by muse, varscan2
- SCART1 | c.571A>T p.R191W | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2
- SCN1A | c.2095G>T p.V699F (on ENST00000303395 / NM_001202435.3; = p.V688F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- SCN2A | c.4540C>T p.P1514S | Missense Mutation (SNP) | VAF 22/557 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- SEC14L5 | c.1059+1G>T p.X353_splice | Splice Site (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- SEMA3C | c.2183A>G p.D728G | Missense Mutation (SNP) | VAF 78/855 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2
- SEPTIN14 | c.431T>A p.L144Q | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SESTD1 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SETDB2 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SHTN1 | c.172+1G>T p.X58_splice | Splice Site (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- SLC25A28 | c.1029G>A p.W343* | Nonsense Mutation (SNP) | VAF 17/294 reads (6%) | called by muse, mutect2
- SLC4A3 | c.2102G>T p.R701L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- SLC8A3 | c.1050C>A p.S350R | Missense Mutation (SNP) | VAF 58/538 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SLITRK1 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, varscan2
- SLITRK6 | c.1091A>T p.N364I | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, varscan2
- SMARCAL1 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SOSTDC1 | c.385del p.Q129Rfs*31 | Frame Shift Del (DEL) | VAF 24/230 reads (10%) | called by pindel, varscan2
- SP140 | c.1643G>T p.R548M | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- SPACA5B | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2
- SPOCK2 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPON2 | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- ST8SIA3 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 19/508 reads (4%) | PolyPhen probably damaging (0.993); called by muse, mutect2
- STYXL2 | c.471G>C p.R157S | Missense Mutation (SNP) | VAF 64/483 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE2 | c.6190C>T p.L2064F | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SYNE2 | c.7129G>T p.G2377C | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SYNE3 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2
- SYNJ1 | c.3815-1G>T p.X1272_splice | Splice Site (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2
- SYT6 | c.626C>A p.P209H (on ENST00000610222 / NM_001366225.1; = p.P124H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/560 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2
- SYTL5 | c.1290C>G p.C430W | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAAR1 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 61/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TAS2R1 | c.230T>C p.M77T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- TBC1D32 | c.3355G>T p.G1119C | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TBX3 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 44/707 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- TEX55 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 33/351 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.301); called by muse, mutect2
- THPO | c.470G>T p.R157M (on ENST00000649095 / NM_001290003.1; = p.R17M on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/907 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TIGD3 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TMEM196 | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TMEM232 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- TNN | c.3463C>A p.P1155T | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.052); called by muse, mutect2
- TRAV8-2 | c.174C>A p.H58Q | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- TRBV19 | c.7A>C p.N3H | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2
- TRIM35 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TRIO | c.3849T>A p.N1283K | Missense Mutation (SNP) | VAF 36/338 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TUBAL3 | c.63G>T p.W21C | Missense Mutation (SNP) | VAF 50/500 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TXNL4A | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); called by muse, mutect2
- UBQLN2 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- USH2A | c.3121C>A p.H1041N | Missense Mutation (SNP) | VAF 52/666 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.946); called by muse, mutect2
- VWDE | c.2414G>C p.S805T | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- WASF3 | c.1121C>G p.S374* | Nonsense Mutation (SNP) | VAF 26/444 reads (6%) | called by muse, mutect2
- WDR35 | c.1639T>G p.Y547D (on ENST00000345530 / NM_001006657.2; = p.Y536D on NM_020779.4) | Missense Mutation (SNP) | VAF 35/620 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- XIRP1 | c.124T>C p.F42L | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2
- XIRP2 | c.8326C>G p.R2776G (on ENST00000628543; = p.R2951G on NM_152381.6) | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- YIPF6 | c.93C>A p.D31E | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- YY2 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 30/575 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2
- ZBTB16 | c.1696C>G p.R566G | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFP36L1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 44/718 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.298); called by muse, mutect2
- ZMYM5 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 79/655 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZNF106 | c.694A>T p.T232S | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF236 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF862 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF865 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0.03); called by muse, mutect2
- ZSCAN22 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- ABCF2 | c.1113G>C p.L371= | Silent (SNP) | VAF 30/374 reads (8%) | called by muse, mutect2
- ADAD2 | c.1341G>C p.L447= (on ENST00000315906 / NM_001145400.2; = p.L529= on NM_139174.4) | Silent (SNP) | VAF 18/438 reads (4%) | called by muse, mutect2
- ADGRG3 | c.672C>T p.T224= | Silent (SNP) | VAF 25/295 reads (8%) | catalogued as rs991889789; called by muse, mutect2
- ADGRG4 | c.1329C>A p.A443= | Silent (SNP) | VAF 32/334 reads (10%) | catalogued as COSV54953939, COSV54964276; called by muse, mutect2
- ANGPT1 | c.1467A>T p.T489= | Silent (SNP) | VAF 28/360 reads (8%) | called by muse, mutect2
- ANKRD33 | c.762A>T p.G254= (on ENST00000340970 / NM_001304459.2; = p.E446V on NM_182608.4) | Silent (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- APOB | c.4017T>G p.T1339= | Silent (SNP) | VAF 26/403 reads (6%) | called by muse, mutect2
- ARC | c.831C>A p.G277= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- C19orf84 | c.516C>A p.P172= | Silent (SNP) | VAF 68/629 reads (11%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.69C>A p.V23= | Silent (SNP) | VAF 50/510 reads (10%) | called by muse, mutect2
- C2orf16 | c.5640C>T p.P1880= | Silent (SNP) | VAF 44/760 reads (6%) | called by muse, mutect2
- C6orf118 | c.270C>G p.R90= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV57814583, COSV57816797; called by muse, mutect2, varscan2
- CA5A | c.726G>T p.S242= | Silent (SNP) | VAF 21/159 reads (13%) | catalogued as rs562598251; called by muse, mutect2, varscan2
- CACNA1D | c.2694G>T p.L898= (on ENST00000350061 / NM_001128840.3; = p.L918= on NM_000720.4) | Silent (SNP) | VAF 77/551 reads (14%) | called by muse, mutect2, varscan2
- CDR2L | c.378G>T p.V126= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- CFAP65 | c.2808C>A p.P936= | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- CFAP69 | c.1665C>T p.F555= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs375668749; called by muse, mutect2, varscan2
- CHD5 | c.3018C>A p.A1006= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- CRIM1 | c.801G>T p.A267= | Silent (SNP) | VAF 47/579 reads (8%) | called by muse, mutect2
- CTNNA3 | c.1767C>A p.A589= | Silent (SNP) | VAF 10/221 reads (5%) | called by muse, mutect2
- CTSG | c.45G>T p.G15= | Silent (SNP) | VAF 31/474 reads (7%) | called by muse, mutect2
- DCX | c.663G>A p.E221= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as rs1209802720; called by muse, mutect2, varscan2
- DGKK | c.585C>A p.T195= | Silent (SNP) | VAF 15/170 reads (9%) | called by muse, mutect2
- DRC7 | c.2505C>A p.I835= | Silent (SNP) | VAF 21/220 reads (10%) | catalogued as rs866293652; called by muse, mutect2, varscan2
- DSG2 | c.3081A>T p.S1027= | Silent (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- ELFN1 | c.1827C>T p.H609= | Silent (SNP) | VAF 34/472 reads (7%) | catalogued as rs563902266; called by muse, mutect2
- ELFN2 | c.1920C>T p.A640= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- ERI3 | c.984C>T p.F328= | Silent (SNP) | VAF 34/694 reads (5%) | catalogued as rs893823865; called by muse, mutect2
- FAM83C | c.1716C>A p.S572= | Silent (SNP) | VAF 28/271 reads (10%) | called by muse, mutect2, varscan2
- FGF13 | c.513G>C p.L171= | Silent (SNP) | VAF 71/670 reads (11%) | called by muse, mutect2, varscan2
- FOXP3 | c.486C>T p.S162= | Silent (SNP) | VAF 27/267 reads (10%) | catalogued as rs1557116474; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMPD2 | c.1524C>A p.T508= | Silent (SNP) | VAF 30/382 reads (8%) | catalogued as rs750456342; called by muse, mutect2
- GPAT4 | c.861C>T p.H287= | Silent (SNP) | VAF 19/288 reads (7%) | catalogued as rs1463375178; called by muse, mutect2
- GPM6A | c.78C>A p.P26= | Silent (SNP) | VAF 45/350 reads (13%) | catalogued as COSV54545576; called by muse, mutect2, varscan2
- HAND2 | c.612G>T p.T204= | Silent (SNP) | VAF 68/580 reads (12%) | catalogued as COSV64019259; called by muse, mutect2, varscan2
- HEPH | c.1605C>T p.L535= (on ENST00000343002; = p.L268= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/850 reads (4%) | catalogued as COSV57974176; called by muse, mutect2
- HMGB4 | c.283C>A p.R95= | Silent (SNP) | VAF 32/298 reads (11%) | catalogued as rs200543241, COSV53966373; called by muse, mutect2, varscan2
- IGKV1D-43 | c.96C>A p.S32= | Silent (SNP) | VAF 85/395 reads (22%) | called by muse, mutect2, varscan2
- IL3RA | c.261C>T p.N87= | Silent (SNP) | VAF 48/485 reads (10%) | catalogued as rs752222459; called by muse, mutect2, varscan2
- IRX2 | c.546G>A p.P182= | Silent (SNP) | VAF 24/788 reads (3%) | called by muse, mutect2
- ITGA2 | c.1053A>G p.L351= | Silent (SNP) | VAF 48/360 reads (13%) | catalogued as rs759679719; called by muse, mutect2, varscan2
- KCNG2 | c.228C>T p.C76= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs1334082506, COSV60269987; called by muse, mutect2
- KCNH2 | c.1482C>T p.F494= | Silent (SNP) | VAF 46/524 reads (9%) | catalogued as CD1511205; called by muse, mutect2
- KPRP | c.213G>A p.Q71= | Silent (SNP) | VAF 24/426 reads (6%) | catalogued as COSV64221555; called by muse, mutect2
- KRT32 | c.1248C>A p.S416= | Silent (SNP) | VAF 51/603 reads (8%) | called by muse, mutect2
- LOXHD1 | c.615G>A p.E205= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- LRRC37A3 | c.3276C>A p.P1092= | Silent (SNP) | VAF 92/902 reads (10%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1836A>T p.T612= | Silent (SNP) | VAF 19/594 reads (3%) | catalogued as rs1475240877; called by muse, mutect2
- MAP7D2 | c.1335T>A p.L445= | Silent (SNP) | VAF 69/721 reads (10%) | called by muse, mutect2, varscan2
- MNDA | c.456C>A p.S152= | Silent (SNP) | VAF 20/239 reads (8%) | called by muse, mutect2
- MROH5 | c.2748G>A p.L916= | Silent (SNP) | VAF 32/392 reads (8%) | catalogued as rs371841414; called by muse, mutect2
- MUC6 | c.5025C>T p.T1675= | Silent (SNP) | VAF 55/1394 reads (4%) | catalogued as rs1211882088; called by muse, mutect2
- MYO16 | c.852G>T p.V284= | Silent (SNP) | VAF 61/494 reads (12%) | called by muse, mutect2, varscan2
- MYO1A | c.339G>T p.L113= | Silent (SNP) | VAF 56/485 reads (12%) | called by muse, mutect2, varscan2
- NEUROD2 | c.459G>A p.K153= | Silent (SNP) | VAF 29/512 reads (6%) | called by muse, mutect2
- NFKB1 | c.423A>T p.I141= (on ENST00000394820 / NM_001382627.1; = p.I142= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- NOS2 | c.3387T>C p.G1129= | Silent (SNP) | VAF 27/352 reads (8%) | called by muse, mutect2
- NOS2 | c.2349G>A p.L783= | Silent (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- NPAP1 | c.2055C>A p.A685= | Silent (SNP) | VAF 30/348 reads (9%) | called by muse, mutect2
- OGDH | c.2526A>G p.L842= | Silent (SNP) | VAF 24/242 reads (10%) | catalogued as rs765082943, COSV56058445; called by muse, mutect2
- OLFML2B | c.1998G>A p.T666= | Silent (SNP) | VAF 31/403 reads (8%) | catalogued as COSV54194260; called by muse, mutect2
- OR2L2 | c.339C>A p.L113= | Silent (SNP) | VAF 36/441 reads (8%) | called by muse, mutect2
- OR51L1 | c.429T>C p.I143= | Silent (SNP) | VAF 73/498 reads (15%) | catalogued as rs1564822869; called by muse, mutect2, varscan2
- OR5D16 | c.324C>G p.T108= | Silent (SNP) | VAF 28/460 reads (6%) | catalogued as rs1270217515; called by muse, mutect2
- OR6S1 | c.859C>T p.L287= | Silent (SNP) | VAF 52/546 reads (10%) | called by muse, mutect2
- P2RY4 | c.723C>A p.L241= | Silent (SNP) | VAF 48/496 reads (10%) | called by muse, mutect2
- PAXIP1 | c.96C>G p.L32= | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as COSV68186639; called by muse, mutect2
- PCARE | c.789G>A p.Q263= | Silent (SNP) | VAF 20/191 reads (10%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1164C>T p.P388= | Silent (SNP) | VAF 60/582 reads (10%) | catalogued as COSV50689762; called by muse, mutect2, varscan2
- PDGFRB | c.2169G>T p.G723= | Silent (SNP) | VAF 26/258 reads (10%) | catalogued as rs961398213; called by muse, mutect2
- PKD1 | c.258C>T p.L86= | Silent (SNP) | VAF 63/1050 reads (6%) | catalogued as rs1225187971; called by muse, mutect2
- PLG | c.1119G>T p.V373= | Silent (SNP) | VAF 52/431 reads (12%) | catalogued as rs1015329067; called by muse, mutect2, varscan2
- PRKCB | c.330C>A p.S110= | Silent (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- PRR30 | c.222C>T p.G74= | Silent (SNP) | VAF 32/305 reads (10%) | catalogued as rs1309742859; called by muse, mutect2, varscan2
- PTPRN2 | c.429C>T p.G143= | Silent (SNP) | VAF 42/331 reads (13%) | catalogued as rs761365531, COSV67031170; called by muse, mutect2, varscan2
- PYGM | c.2025A>T p.S675= | Silent (SNP) | VAF 24/412 reads (6%) | called by muse, mutect2
- PZP | c.3483C>A p.S1161= | Silent (SNP) | VAF 30/276 reads (11%) | catalogued as COSV54355807, COSV99739758; called by muse, mutect2, varscan2
- RABGAP1 | c.2004C>T p.F668= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- RANBP3 | c.126G>T p.R42= | Silent (SNP) | VAF 27/241 reads (11%) | catalogued as rs769227444; called by muse, mutect2
- REV3L | c.1770G>A p.L590= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV62625792; called by muse, mutect2
- RNF168 | c.81C>T p.V27= | Silent (SNP) | VAF 17/459 reads (4%) | called by muse, mutect2
- SFMBT2 | c.2391G>T p.P797= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- SMARCA5 | c.2022C>T p.I674= | Silent (SNP) | VAF 37/382 reads (10%) | catalogued as COSV51642203; called by muse, mutect2
- SMPD3 | c.1476G>T p.S492= | Silent (SNP) | VAF 43/416 reads (10%) | called by muse, mutect2
- SMPD4 | c.2484G>T p.V828= (on ENST00000409031 / NM_017951.4; = p.V799= on NM_017751.4) | Silent (SNP) | VAF 74/816 reads (9%) | called by muse, mutect2
- SPATA24 | c.180G>T p.L60= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, varscan2
- STOX2 | c.1431G>C p.R477= | Silent (SNP) | VAF 27/617 reads (4%) | catalogued as rs1188504666; called by muse, mutect2
- SYNM | c.3963C>A p.T1321= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- TF | c.297G>T p.V99= | Silent (SNP) | VAF 86/789 reads (11%) | catalogued as COSV53919850; called by muse, mutect2, varscan2
- TLR3 | c.759G>T p.L253= | Silent (SNP) | VAF 34/276 reads (12%) | called by muse, varscan2
- TP53BP1 | c.5040C>T p.A1680= | Silent (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- TRPC4 | c.1722A>T p.S574= | Silent (SNP) | VAF 18/148 reads (12%) | called by muse, mutect2, varscan2
- WDFY4 | c.2673C>T p.H891= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- WDR87 | c.4893C>A p.A1631= | Silent (SNP) | VAF 19/493 reads (4%) | catalogued as COSV58205822; called by muse, mutect2
- XKR3 | c.633C>A p.A211= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2
- ZNF765 | c.75G>T p.L25= | Silent (SNP) | VAF 50/589 reads (8%) | called by muse, varscan2
- ZNF853 | c.1275G>T p.A425= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as rs1185667739; called by muse, mutect2, varscan2
- ZYG11A | c.852G>T p.L284= | Silent (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- AANAT | c.-22C>A | 5'UTR (SNP) | VAF 37/424 reads (9%) | called by muse, mutect2
- AC008592.1 | chr5:95856958 G>T | 5'Flank (SNP) | VAF 39/345 reads (11%) | called by muse, mutect2, varscan2
- AC064807.1 | n.834C>A | RNA (SNP) | VAF 30/414 reads (7%) | catalogued as rs368455168; called by muse, mutect2
- AC136759.1 | n.517C>A | RNA (SNP) | VAF 54/438 reads (12%) | called by muse, mutect2, varscan2
- ANKS1A | c.*1641C>T | 3'UTR (SNP) | VAF 64/400 reads (16%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501701 C>A | 5'Flank (SNP) | VAF 35/475 reads (7%) | called by muse, mutect2
- ARHGAP25 | c.261+205G>A | Intron (SNP) | VAF 24/578 reads (4%) | called by muse, mutect2
- ATRNL1 | c.-126G>T | 5'UTR (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- BMT2 | c.160+4329G>T | Intron (SNP) | VAF 17/319 reads (5%) | called by muse, mutect2
- C2orf72 | c.*200C>A | 3'UTR (SNP) | VAF 14/84 reads (17%) | called by muse, mutect2, varscan2
- CAPN2 | c.-80G>T | 5'UTR (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- CATSPER4 | c.*12G>T | 3'UTR (SNP) | VAF 41/448 reads (9%) | called by muse, mutect2
- CELSR1 | c.7760-9T>G | Intron (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- CELSR1 | c.7760-10C>A | Intron (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- CERKL | chr2:181657099 C>T | 5'Flank (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- CIB4 | c.186+5820C>A | Intron (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- CLRN1 | c.254-3913G>T | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- CRMP1 | chr4:5892856 C>A | 5'Flank (SNP) | VAF 11/188 reads (6%) | catalogued as COSV61482292; called by muse, mutect2
- CXCL12 | c.*350G>T | 3'UTR (SNP) | VAF 62/828 reads (7%) | called by muse, mutect2
- CXCL12 | c.*349G>C | 3'UTR (SNP) | VAF 63/827 reads (8%) | called by muse, mutect2
- DAZL | c.-7C>T | 5'UTR (SNP) | VAF 99/773 reads (13%) | catalogued as rs751410249; called by muse, mutect2, varscan2
- DYNC1I1 | c.-9-393G>T | Intron (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ECSIT | c.*10G>T | 3'UTR (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- EYS | c.1767-8040G>A | Intron (SNP) | VAF 15/116 reads (13%) | called by mutect2, varscan2
- FUNDC2P2 | n.145G>T | RNA (SNP) | VAF 14/193 reads (7%) | called by muse, mutect2
- GCSAML | c.-56-10384C>A | Intron (SNP) | VAF 42/381 reads (11%) | called by muse, mutect2, varscan2
- GIMAP6 | c.*35C>A | 3'UTR (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- GSPT1 | c.-63+632C>G | Intron (SNP) | VAF 110/426 reads (26%) | called by muse, mutect2, varscan2
- GTF3C5 | c.1167+376G>T | Intron (SNP) | VAF 32/486 reads (7%) | called by muse, mutect2
- HEXA | c.805+12G>A | Intron (SNP) | VAF 52/464 reads (11%) | called by muse, mutect2, varscan2
- HUWE1 | c.693+16G>T | Intron (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- ITGB1BP1 | c.-36+52G>A | Intron (SNP) | VAF 14/262 reads (5%) | called by muse, mutect2
- LAMA4 | c.195+149T>A | Intron (SNP) | VAF 88/694 reads (13%) | called by muse, mutect2, varscan2
- MGAM | c.4619-1189G>T | Intron (SNP) | VAF 52/887 reads (6%) | catalogued as rs749210241; called by muse, mutect2
- MPRIP | c.2164-3880G>T | Intron (SNP) | VAF 50/459 reads (11%) | called by muse, mutect2, varscan2
- MUC19 | n.5375C>A | RNA (SNP) | VAF 29/413 reads (7%) | called by muse, mutect2
- NADSYN1 | c.799-1044G>T | Intron (SNP) | VAF 29/183 reads (16%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18340412 G>T | 5'Flank (SNP) | VAF 71/616 reads (12%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156716 C>A | 3'Flank (SNP) | VAF 33/299 reads (11%) | called by muse, mutect2, varscan2
- PITX2 | c.185-958G>A | Intron (SNP) | VAF 59/988 reads (6%) | catalogued as rs747962392, COSV99049775; called by muse, mutect2
- PLAC9 | chr10:80132697 G>C | 5'Flank (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- RAB34 | c.-307C>G | 5'UTR (SNP) | VAF 29/646 reads (4%) | catalogued as rs985594762; called by muse, mutect2
- RCC1L | c.1058-534A>G | Intron (SNP) | VAF 55/405 reads (14%) | called by muse, mutect2, varscan2
- RGS2 | c.-24C>A | 5'UTR (SNP) | VAF 78/683 reads (11%) | catalogued as rs541337584, COSV99343289, COSV99343445; called by muse, mutect2, varscan2
- RHOJ | c.*45C>A | 3'UTR (SNP) | VAF 42/644 reads (7%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34158896 C>A | 5'Flank (SNP) | VAF 30/388 reads (8%) | called by muse, mutect2
- RP2 | c.-20G>T | 5'UTR (SNP) | VAF 64/672 reads (10%) | called by muse, mutect2
- RUNX1T1 | c.88+13262G>T | Intron (SNP) | VAF 18/206 reads (9%) | catalogued as rs966820811; called by muse, mutect2
- SLC11A2 | c.122-503C>T | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as rs781169969; called by muse, mutect2, varscan2
- SLC7A5P2 | n.213G>T | RNA (SNP) | VAF 33/603 reads (5%) | called by muse, mutect2
- SSPOP | n.11829G>T | RNA (SNP) | VAF 25/423 reads (6%) | called by muse, mutect2
- SSPOP | n.12685G>T | RNA (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.14347G>T | RNA (SNP) | VAF 25/284 reads (9%) | called by muse, mutect2
- SVIL2P | n.1686G>T | RNA (SNP) | VAF 25/327 reads (8%) | called by muse, mutect2
- TAL1 | c.*144C>A | 3'UTR (SNP) | VAF 72/1170 reads (6%) | called by muse, mutect2
- TIMP1 | c.329-69C>G | Intron (SNP) | VAF 30/362 reads (8%) | called by muse, mutect2
- TRIM61 | c.526-1949C>A | Intron (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- TRPA1 | c.3150-14G>T | Intron (SNP) | VAF 34/354 reads (10%) | called by muse, mutect2
- TSNAXIP1 | c.-69A>T | 5'UTR (SNP) | VAF 30/400 reads (8%) | called by muse, mutect2
- TSR2 | c.*2922G>A | 3'UTR (SNP) | VAF 34/620 reads (5%) | catalogued as rs552289674; called by muse, mutect2
- TUBB7P | n.79G>T | RNA (SNP) | VAF 32/506 reads (6%) | called by muse, mutect2
- UGT2B27P | n.734T>A | RNA (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- USF2 | c.951+29G>A | Intron (SNP) | VAF 115/577 reads (20%) | catalogued as rs569286718; called by muse, mutect2, varscan2
- WHRN | c.837+69G>T | Intron (SNP) | VAF 58/847 reads (7%) | catalogued as rs755347297; called by muse, mutect2
